Somatic mutation profile of tumor specimen TCGA-S9-A6WG-01A (aliquot TCGA-S9-A6WG-01A-11D-A33T-08) from TCGA case TCGA-S9-A6WG, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.5 years (11,509 days).
Specimen TCGA-S9-A6WG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 916bfa7e-9bdc-4593-87b4-0f921c6d4c32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WG-10A (Blood Derived Normal), aliquot TCGA-S9-A6WG-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/844eb81b-7ca8-4843-9313-3d66a4967685

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 4, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 51/182 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 31/131 reads (24%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- TP53 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 32/116 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs397514495, CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP11 | c.3260A>G p.D1087G | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV99213641; called by muse, mutect2
- ATRX | c.5215C>T p.R1739* | Nonsense Mutation (SNP) | VAF 54/98 reads (55%) | catalogued as COSV64873412; called by muse, mutect2, varscan2
- CDH4 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.453); catalogued as rs1051676; called by muse, mutect2, varscan2
- COL19A1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); catalogued as rs1178902584, COSV100505503, COSV59572208; called by muse, mutect2, varscan2
- CYP4F22 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.746); catalogued as rs146689227, COSV54108972; called by muse, mutect2, varscan2
- FMR1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54423800, COSV54425108; called by muse, mutect2
- HEXIM2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs957909206, COSV100217875; called by muse, mutect2, varscan2
- HOXA11 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.957); catalogued as rs1250169824, COSV99135891; called by muse, mutect2, varscan2
- MYSM1 | c.1583C>A p.A528D | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV101284026; called by muse, mutect2, varscan2
- SCN10A | c.4514C>T p.T1505M | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs184521520, COSV101479285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEG | c.4777C>T p.R1593* | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100403649; called by muse, mutect2, varscan2
- TMC1 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 15/137 reads (11%) | catalogued as COSV52776193, COSV99918874; called by muse, mutect2, varscan2
- CFAP54 | c.5232C>T p.H1744= | Silent (SNP) | VAF 66/207 reads (32%) | catalogued as rs114864261, COSV100733022; called by muse, mutect2, varscan2
- L1CAM | c.1569G>A p.G523= | Silent (SNP) | VAF 66/231 reads (29%) | catalogued as COSV62828317; called by muse, mutect2, varscan2
- SPNS3 | c.795C>T p.L265= | Silent (SNP) | VAF 65/239 reads (27%) | catalogued as rs757109921, COSV61072888; called by muse, mutect2, varscan2
- ZNF677 | c.105C>T p.D35= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as rs763231628, COSV61719780, COSV61720670; called by muse, mutect2, varscan2
